Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3591, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3591-01A (Primary Tumor).

Diagnosis/ diagnoses:

Rectosigmoid resection preparation with a moderately differentiated adenocarcinoma of the colorectal type, located 2 cm above the dentate line, and a maximum of 3 cm in diameter, with wide infiltration of the perirectal fatty tissue. Tumor-free regional lymph nodes. Resection margins are tumor-free. The minimum distance between the tumor and the circumferential resection margin is 1.5 mm. Peritumorous, focally marked, chronic, florid, fibrosing and resorptive cellular inflammation.

Tumor stage: pT3 pN0 (0/16) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file c115a374-2e3b-401a-9f3a-23c1063cd3ad (TCGA-AG-3591.EE04F997-1499-46B8-B35C-B7671367829E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).